Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A054, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A054-01A (Primary Tumor).

ICD-0-3

adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 h 5/2/11

Specimens Submitted:

- 1: SP: Uterus, cervix, left tube and ovary
- 2: SP: Sigmoid nodule
- 3: SP: Right tube and ovary
- 4: SP: Posterior cul-de-sac nodule
- 5: SP: Right external iliac lymph nodes
- 6: SP: Right hypogastric lymph nodes
- 7: SP: Right obturator lymph nodes
- 8: SP: Right common iliac lymph nodes
- 9: SP: Left external iliac lymph nodes
- 10: SP: Left obturator lymph nodes
- 11: SP: Left common iliac lymph nodes
- 12: SP: Left para-aortic lymph nodes
- 13: SP: Omentum
- 14: SP: Right para-aortic lymph nodes

DIAGNOSIS:

- 1) UTERUS, CERVIX, LEFT OVARY AND FALLOPIAN TUBE; TOTAL HYSTERECTOMY AND SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE III (> 50% SOLID GROWTH) (SEE NOTE), NUCLEAR GRADE 2.
- THE TUMOR INVADERS THROUGH THE ENTIRE THICKNESS OF THE MYOMETRIUM AND INVADERS FIBROADIPOSE TISSUE ATTACHED TO THE UTERUS AND THE UTERINE SEROSA.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- TUMOR INVOLVES THE POSTERIOR LOWER UTERINE SEGMENT.
- VASCULAR INVASION IS PRESENT.
- THE MYOMETRIUM IS UNREMARKABLE.
- THE LEFT OVARY SHOWS A FIBROTHEROMA.
- THE LEFT FALLOPIAN TUBE IS UNREMARKABLE.

NOTE: PORTIONS OF THE TUMOR APPEAR UNDIFFERENTIATED.

- 2) SOFT TISSUE, SIGMOID NODULE; EXCISION:
- METASTATIC CARCINOMA, SIMILAR TO THAT SEEN IN PART 1.

** Continued on next page **

Source: NCI Genomic Data Commons file 338a343c-c62c-4f50-9f12-c65b4b60fdb4 (TCGA-AP-A054.72028DF7-DAD0-487E-914B-C3AA69A1E6C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).